Somatic mutation profile of tumor specimen TCGA-B5-A11J-01A (aliquot TCGA-B5-A11J-01A-11D-A122-09) from TCGA case TCGA-B5-A11J, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 64.3 years (23,485 days).
Specimen TCGA-B5-A11J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09564449-7c2b-49da-8716-5f5a73321337.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11J-10A (Blood Derived Normal), aliquot TCGA-B5-A11J-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18bdc407-8f5e-4f20-931f-d26168150384

The open-access MAF lists 538 somatic variants for this specimen: 418 protein-altering or splice-affecting, 110 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 266, Silent 110, Frame Shift Del 86, Nonsense Mutation 25, Frame Shift Ins 22, Splice Site 8, Splice Region 5, Intron 4, In Frame Del 4, RNA 3, 3'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.275_277del p.F92del | In Frame Del (DEL) | VAF 15/142 reads (11%) | catalogued as rs730880388; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BCL10 | c.136dup p.I46Nfs*4 | Frame Shift Ins (INS) | VAF 62/190 reads (33%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 48/148 reads (32%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 129/314 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 28/69 reads (41%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NOTCH3 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.893); catalogued as rs1202763005, HM070085, COSV54643175; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PANK2 | c.1257del p.F419Lfs*31 (on ENST00000316562 / NM_153638.3; = p.F128Lfs*31 on NM_024960.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | catalogued as rs1568574931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3R1 | c.1746-17_1756del p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (DEL) | VAF 117/433 reads (27%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 105/272 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs797044910, CM110138, CM141438, COSV64293188, COSV64296384, COSV64307484; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.195C>G p.Y65* | Nonsense Mutation (SNP) | VAF 65/164 reads (40%) | hotspot (GDC flag); catalogued as rs878853936, CM110159, CM1513010, COSV64291341, COSV64293906; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC16A1 | c.41dup p.D15Rfs*34 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADAC | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV51758189; called by muse, mutect2, varscan2
- ABCA12 | c.7655T>C p.L2552S (on ENST00000272895 / NM_173076.3; = p.L2234S on NM_015657.3) | Missense Mutation (SNP) | VAF 100/212 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55969434; called by muse, mutect2, varscan2
- ABHD13 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV65535278; called by muse, mutect2, varscan2
- ACSF3 | c.1158G>T p.Q386H | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV58080486; called by muse, mutect2, varscan2
- ADAM19 | c.1309-1G>T p.X437_splice | Splice Site (SNP) | VAF 41/94 reads (44%) | catalogued as COSV57435662, COSV99976513; called by muse, mutect2, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 24/140 reads (17%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADAMTS7 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs761311542, COSV66308741; called by muse, mutect2
- ADGRA1 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); catalogued as COSV101658575; called by muse, mutect2, varscan2
- ADGRB2 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV57076896; called by muse, mutect2
- AKAP11 | c.1951G>T p.A651S | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50299318; called by muse, mutect2, varscan2
- AKAP8L | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV68473290, COSV68474138; called by muse, mutect2, varscan2
- ALMS1 | c.4820del p.K1607Rfs*9 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | catalogued as rs758098717; called by mutect2, pindel, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 74/502 reads (15%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- AP4M1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs748967782, COSV57998033; called by muse, mutect2, varscan2
- ARC | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV63079201; called by muse, mutect2, varscan2
- ARHGAP33 | c.2777A>G p.Y926C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV50140888; called by muse, mutect2, varscan2
- ARHGAP4 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557103129, COSV61686667; called by muse, mutect2, varscan2
- ARMC4 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs556371991, COSV100537198, COSV59467284; called by muse, mutect2, varscan2
- ARRB2 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 104/264 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs780961076, COSV52618024; called by muse, mutect2, varscan2
- ASNS | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1251417315, COSV51554528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPM | c.9449G>T p.W3150L | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV54135044; called by muse, mutect2, varscan2
- ATP1A3 | c.3037C>T p.R1013C (on ENST00000545399 / NM_001256214.2; = p.R1000C on NM_152296.5) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV57489907; called by muse, mutect2, varscan2
- ATP1B3 | c.669+1G>A p.X223_splice | Splice Site (SNP) | VAF 11/244 reads (5%) | catalogued as COSV99657122; called by muse, mutect2
- ATP2B3 | c.3637C>T p.L1213F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV54856223; called by muse, mutect2, varscan2
- ATP6V1C2 | c.638+3_638+6del p.X213_splice | Splice Site (DEL) | VAF 71/205 reads (35%) | catalogued as rs1268283941; called by pindel, varscan2
- AVEN | c.962A>G p.Q321R | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as rs1400761524, COSV60736482; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972dup p.E992* | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | catalogued as rs35951843; called by mutect2, varscan2
- B4GALT4 | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV63296299; called by muse, mutect2, varscan2
- BACE2 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs756983976, COSV57741887; called by muse, mutect2, varscan2
- BACH1 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs377002114; called by muse, mutect2, varscan2
- BARHL1 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.131); catalogued as rs966238637, COSV55038483; called by muse, mutect2, varscan2
- BARX2 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs755171720, COSV55651714; called by muse, mutect2, varscan2
- BIRC2 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 61/127 reads (48%) | catalogued as COSV57162558; called by muse, mutect2, varscan2
- BLNK | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV56413510; called by muse, mutect2, varscan2
- BRCA2 | c.2962G>A p.D988N | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); catalogued as COSV66459069; called by muse, mutect2, varscan2
- C18orf25 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.05); catalogued as COSV56367993; called by muse, mutect2, varscan2
- C1R | c.1015C>T p.Q339* (on ENST00000536053 / NM_001354346.2; = p.Q325* on NM_001733.7) | Nonsense Mutation (SNP) | VAF 58/270 reads (21%) | catalogued as COSV73293818; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 76/283 reads (27%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, varscan2
- C7 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 107/303 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57478152; called by muse, mutect2, varscan2
- C7orf61 | c.571del p.R191Dfs*8 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs767078637; called by mutect2, pindel, varscan2
- CABIN1 | c.4693C>T p.H1565Y | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV99572646; called by muse, mutect2, varscan2
- CACNA1A | c.4919C>T p.T1640I | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV100800725; called by muse, mutect2
- CACNG7 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99711835; called by muse, mutect2
- CBLC | c.1399G>T p.G467* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV54324695; called by muse, mutect2, varscan2
- CCDC173 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 165/450 reads (37%) | catalogued as rs770658227, COSV69573400; called by muse, mutect2, varscan2
- CCDC39 | c.1045dup p.T349Nfs*2 | Frame Shift Ins (INS) | VAF 46/371 reads (12%) | catalogued as rs747980515; called by mutect2, pindel, varscan2
- CEP131 | c.2443C>T p.R815W (on ENST00000269392 / NM_001319228.2; = p.R812W on NM_014984.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746435622, COSV53950321; called by muse, mutect2, varscan2
- CEP97 | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 15/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100511523; called by muse, mutect2
- CERS2 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 75/179 reads (42%) | catalogued as rs1464303489, COSV54989488; called by muse, mutect2, varscan2
- CFAP36 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV55407717; called by muse, mutect2, varscan2
- CGB8 | c.438del p.S147Afs*? | Frame Shift Del (DEL) | VAF 31/192 reads (16%) | catalogued as COSV56822738; called by mutect2, pindel, varscan2
- CGN | c.709T>G p.S237A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV54972262; called by muse, mutect2, varscan2
- CHAF1B | c.1184C>A p.P395H | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV58441056; called by muse, mutect2, varscan2
- CHD3 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 90/225 reads (40%) | catalogued as COSV57878363; called by muse, mutect2, varscan2
- CHEK2 | c.758C>A p.S253* (on ENST00000382580 / NM_001005735.2; = p.S210* on NM_007194.4) | Nonsense Mutation (SNP) | VAF 38/195 reads (19%) | catalogued as COSV60423821; called by muse, mutect2, varscan2
- CMAS | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 144/398 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1232782429, COSV57557202; called by muse, mutect2, varscan2
- COMP | c.216C>T p.C72= | Splice Region (SNP) | VAF 12/88 reads (14%) | catalogued as COSV55875935; called by muse, mutect2, varscan2
- COPA | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.041); catalogued as COSV54107121; called by muse, mutect2, varscan2
- CPXM2 | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1455207884, COSV53867011, COSV53869728; called by muse, mutect2, varscan2
- CROCC | c.2203C>T p.Q735* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs374648648, COSV65011374; called by muse, mutect2
- CROCC | c.3119A>G p.E1040G | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV65013916; called by muse, mutect2, varscan2
- CSF2RB | c.2074C>A p.P692T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV53259798, COSV53261700; called by muse, mutect2, varscan2
- CST1 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 50/216 reads (23%) | catalogued as rs756924682; called by mutect2, varscan2
- CUX1 | c.3634C>T p.R1212W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52909305; called by muse, mutect2, varscan2
- CWC27 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66887559; called by muse, mutect2, varscan2
- CYP2A7 | c.1118G>T p.R373M | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.963); catalogued as COSV52504379; called by muse, mutect2, varscan2
- CYTH2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57308929; called by muse, mutect2, varscan2
- DDIT4L | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as COSV56767831; called by muse, mutect2, varscan2
- DEAF1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs765017164, COSV51562933; called by muse, mutect2, varscan2
- DLC1 | c.2045G>A p.S682N (on ENST00000276297 / NM_001348081.2; = p.S245N on NM_006094.5) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV52318735; called by mutect2, varscan2
- DLG3 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV52085554; called by muse, mutect2, varscan2
- DNAH5 | c.3031C>T p.R1011W | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as rs928800148, COSV54238591; called by muse, mutect2, varscan2
- DNAH9 | c.8947G>A p.E2983K | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as rs202196562, COSV52366440; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | catalogued as rs782552436; called by mutect2, varscan2
- DSG3 | c.2342A>G p.D781G | Missense Mutation (SNP) | VAF 102/274 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV57128341; called by muse, mutect2, varscan2
- DSN1 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1398178695, COSV65519115; called by muse, mutect2, varscan2
- DSP | c.7709G>C p.S2570T | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as COSV65794393; called by muse, mutect2, varscan2
- DSTN | c.308dup p.L103Ffs*12 | Frame Shift Ins (INS) | VAF 16/84 reads (19%) | catalogued as rs750962255; called by mutect2, varscan2
- DYSF | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs759065714, COSV50509422; called by muse, mutect2, varscan2
- DZIP1 | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.793); catalogued as rs1163768590, COSV61268213; called by muse, mutect2, varscan2
- EIF3A | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs182093925; called by muse, mutect2, varscan2
- EIF5B | c.3012+1G>A p.X1004_splice | Splice Site (SNP) | VAF 44/212 reads (21%) | catalogued as COSV56812050; called by muse, varscan2
- EMG1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 124/535 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs1555152914, COSV54643253; called by muse, mutect2, varscan2
- EMILIN1 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs756693825, COSV53156297; called by muse, mutect2, varscan2
- ENPP5 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1354392455, COSV57909042; called by muse, mutect2, varscan2
- EPB41 | c.1070C>G p.P357R (on ENST00000343067 / NM_001166005.2; = p.P148R on NM_004437.4) | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202197419; called by muse, mutect2, varscan2
- ERN2 | c.2773G>T p.G925W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as COSV55623576; called by muse, mutect2, varscan2
- ESYT1 | c.2507C>T p.T836I | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.202); catalogued as rs1484618739, COSV57275250; called by muse, mutect2, varscan2
- ETNK1 | c.159C>A p.L53= | Splice Region (SNP) | VAF 33/91 reads (36%) | catalogued as COSV56888025; called by muse, mutect2, varscan2
- EWSR1 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); catalogued as rs755735886, COSV58426183; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 52/252 reads (21%) | catalogued as rs766589051; called by pindel, varscan2
- FAM81A | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1181338730, COSV55678546; called by muse, mutect2, varscan2
- FAM83B | c.68A>G p.H23R | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60924964; called by muse, mutect2, varscan2
- FAM83B | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs553145456, COSV60922309; called by muse, mutect2, varscan2
- FANCE | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 94/353 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57690685; called by muse, mutect2, varscan2
- FLAD1 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52696670; called by muse, mutect2, varscan2
- FN1 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.909); catalogued as rs775576039, COSV60555344; called by muse, mutect2
- FNDC1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs370527562; called by muse, mutect2, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 53/261 reads (20%) | catalogued as rs764290022, COSV57049642; called by mutect2, pindel, varscan2
- FRMPD2 | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100563471; called by muse, mutect2, varscan2
- FRY | c.3271C>T p.R1091W | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66575607; called by muse, mutect2, varscan2
- FRYL | c.4532T>C p.L1511P | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as COSV51956018; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSTL4 | c.1511T>C p.V504A | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54780278; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 32/196 reads (16%) | catalogued as rs756304971; called by mutect2, varscan2
- GABRG1 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV54949305, COSV54958935; called by muse, mutect2, varscan2
- GAK | c.3417del p.A1141Pfs*15 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs761107041; called by mutect2, pindel, varscan2
- GALNT13 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV67227762, COSV67231852; called by muse, mutect2, varscan2
- GCM2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs979559861, COSV65276222; called by muse, mutect2, varscan2
- GDF10 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs782520978; called by muse, mutect2, varscan2
- GLIS1 | c.1675C>A p.H559N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV56553395; called by muse, mutect2, varscan2
- GNPTAB | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 125/333 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.123); catalogued as COSV71820788; called by muse, mutect2, varscan2
- GPALPP1 | c.40T>A p.F14I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1468648566, COSV63151755; called by muse, mutect2, varscan2
- GPATCH2L | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776356960, COSV55046856; called by muse, mutect2, varscan2
- GPHN | c.2107A>G p.M703V (on ENST00000315266 / NM_001377519.1; = p.M736V on NM_020806.5) | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs773187265, COSV100015264; called by muse, mutect2
- GRHPR | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs760782027, COSV100546794; ClinVar: uncertain significance; called by muse, mutect2
- GRK5 | c.460A>G p.R154G | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV64867166; called by muse, mutect2, varscan2
- GYPE | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 221/507 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV62262148; called by muse, mutect2, varscan2
- HARS1 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV56908515; called by muse, mutect2, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 190/498 reads (38%) | catalogued as rs34558496; called by mutect2, varscan2
- HBP1 | c.808A>T p.S270C | Missense Mutation (SNP) | VAF 157/373 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56018823; called by muse, mutect2, varscan2
- HCLS1 | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs557856417, COSV58858773; called by muse, mutect2, varscan2
- HCN1 | c.1937C>A p.T646N | Missense Mutation (SNP) | VAF 144/360 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV57527996; called by muse, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 126/359 reads (35%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HEY2 | c.878C>A p.A293E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV64240415; called by muse, varscan2
- HIVEP1 | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as COSV65103832; called by muse, mutect2, varscan2
- HMCES | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs148008790; called by muse, mutect2, varscan2
- HSF2BP | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV52358393; called by muse, mutect2, varscan2
- HTR1F | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as rs772688320, COSV60389602; called by muse, mutect2, varscan2
- HTRA4 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 87/409 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs770040324, COSV56758646, COSV56760478; called by muse, mutect2, varscan2
- HUNK | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.284); catalogued as rs377150590, COSV54225718; called by muse, mutect2, varscan2
- HUNK | c.1892del p.P631Qfs*27 | Frame Shift Del (DEL) | VAF 31/75 reads (41%) | catalogued as rs35859052, COSV99528973; called by mutect2, pindel, varscan2
- HUWE1 | c.11210C>T p.T3737M | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1441168477, COSV53357729, COSV99470786; called by muse, mutect2, varscan2
- HYDIN | c.1771A>G p.N591D | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55493543; called by muse, mutect2, varscan2
- IFITM5 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs762079301, COSV101164273; called by mutect2, varscan2
- IGF1R | c.4010G>A p.R1337H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs759627092, COSV51339095; called by muse, mutect2, varscan2
- IGF2BP1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs752960224, COSV51734129; called by muse, mutect2, varscan2
- IL21R | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1385136152, COSV61971760, COSV61973084; called by muse, mutect2, varscan2
- ILVBL | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as rs757591847, COSV54621396; called by muse, mutect2, varscan2
- ING4 | c.251A>G p.Q84R | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58555977; called by muse, mutect2, varscan2
- INPPL1 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1165709765, COSV53357878; called by muse, mutect2, varscan2
- ITGB3 | c.1476G>A p.W492* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as CM114723, COSV71384826; called by muse, mutect2, varscan2
- ITGB4 | c.4085G>A p.R1362K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.304); catalogued as COSV99563268; called by muse, mutect2
- ITGB5 | c.2018-2A>G p.X673_splice | Splice Site (SNP) | VAF 26/59 reads (44%) | catalogued as COSV56151592; called by muse, mutect2, varscan2
- IWS1 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 131/287 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV54870500; called by muse, mutect2, varscan2
- JAK1 | c.2515C>T p.R839* | Nonsense Mutation (SNP) | VAF 24/179 reads (13%) | catalogued as rs181919006, COSV61094649; called by muse, mutect2, varscan2
- KAT14 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs368262295; called by muse, mutect2, varscan2
- KCNS2 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV54639969; called by muse, mutect2, varscan2
- KCNU1 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1418544947, COSV67758507; called by muse, mutect2, varscan2
- KDM1B | c.2125G>A p.V709M (on ENST00000449850; = p.V476M on NM_153042.4) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs748774757, COSV52813298; called by muse, mutect2, varscan2
- KIAA1109 | c.380T>C p.L127S | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99145669; called by muse, mutect2
- KIAA1109 | c.1205del p.N402Ifs*9 | Frame Shift Del (DEL) | VAF 25/126 reads (20%) | catalogued as COSV52685780; called by mutect2, pindel
- KIAA1109 | c.9630G>T p.Q3210H | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV52685565; called by muse, mutect2, varscan2
- KIAA1210 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 89/346 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV68178699; called by muse, mutect2, varscan2
- KIAA2026 | c.4507G>A p.A1503T | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV67356763; called by muse, mutect2, varscan2
- KIAA2026 | c.2069del p.K690Rfs*3 | Frame Shift Del (DEL) | VAF 26/206 reads (13%) | catalogued as rs1220524818; called by mutect2, varscan2
- KIF5A | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs770302674, COSV54057295; called by muse, mutect2, varscan2
- KIF6 | c.1019A>G p.Q340R | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54687583; called by muse, mutect2, varscan2
- KISS1R | c.308A>T p.Y103F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.21); catalogued as COSV52257892; called by muse, mutect2, varscan2
- KMT2A | c.9139G>A p.V3047M | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as rs1359868730, COSV63290196; called by muse, mutect2, varscan2
- KMT2B | c.1376C>A p.P459H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.99); catalogued as COSV52891849; called by muse, mutect2, varscan2
- KMT2D | c.3935G>A p.R1312H | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762289838, COSV56469192; called by muse, mutect2, varscan2
- KMT5A | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV57864183; called by muse, mutect2, varscan2
- KRT26 | c.714del p.N239Tfs*2 | Frame Shift Del (DEL) | VAF 56/266 reads (21%) | catalogued as rs1007245915; called by mutect2, pindel, varscan2
- LRP1 | c.6755C>A p.P2252H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.276); catalogued as COSV54520079; called by muse, mutect2, varscan2
- LRP1 | c.8960G>A p.S2987N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs752903769, COSV54520093; called by muse, mutect2, varscan2
- LRP1 | c.12986G>A p.R4329H | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); catalogued as rs558649900, COSV54504581; called by muse, mutect2, varscan2
- LZTR1 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.196); catalogued as rs371593909; called by muse, varscan2
- MACC1 | c.77T>C p.M26T | Missense Mutation (SNP) | VAF 130/359 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV60545128; called by muse, mutect2, varscan2
- MACF1 | c.1481T>C p.L494P | Missense Mutation (SNP) | VAF 16/113 reads (14%) | catalogued as COSV58391271; called by muse, mutect2, varscan2
- MAG | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV62702049; called by muse, mutect2, varscan2
- MAGEH1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.038); catalogued as rs372274274, COSV61678974; called by muse, mutect2, varscan2
- MAN1A2 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.18); catalogued as rs1376715284, COSV62980142; called by muse, mutect2, varscan2
- MAP10 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV69364450; called by muse, mutect2, varscan2
- MAPK14 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 180/435 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs867617022, COSV57697063; called by muse, mutect2, varscan2
- MARVELD2 | c.1550del p.K517Rfs*16 | Frame Shift Del (DEL) | VAF 58/146 reads (40%) | catalogued as rs753107989; called by mutect2, varscan2
- MAST4 | c.5861G>A p.R1954H (on ENST00000403625 / NM_001164664.2; = p.R1765H on NM_015183.3) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs750796760, COSV55135429; called by muse, mutect2, varscan2
- MATN2 | c.2795_2798del p.V932Efs*3 | Frame Shift Del (DEL) | VAF 112/287 reads (39%) | catalogued as rs759420346; called by mutect2, pindel, varscan2
- MBOAT1 | c.163C>A p.R55S | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV61126882; called by muse, mutect2, varscan2
- MCCC1 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); catalogued as COSV55610659; called by muse, mutect2, varscan2
- MDM2 | c.961del p.L321Ffs*52 | Frame Shift Del (DEL) | VAF 65/170 reads (38%) | catalogued as rs746910913; called by mutect2, pindel, varscan2
- MED15 | c.1961T>C p.I654T (on ENST00000263205 / NM_001003891.3; = p.I614T on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV99487336; called by muse, mutect2, varscan2
- MGAM | c.4384C>G p.L1462V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as COSV72075244; called by muse, mutect2, varscan2
- MMP3 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 61/402 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as rs780504353, COSV55407317; called by muse, mutect2, varscan2
- MROH5 | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV71302349; called by muse, mutect2, varscan2
- MRPS11 | c.411G>A p.A137= | Splice Region (SNP) | VAF 20/97 reads (21%) | catalogued as rs779356539, COSV57914862, COSV57915376; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 40/104 reads (38%) | catalogued as rs768684761; called by mutect2, varscan2
- MTMR1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 130/314 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.09); catalogued as COSV64899165; called by muse, mutect2, varscan2
- MUC16 | c.15256C>T p.R5086C | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as rs751244335, COSV67481460; called by muse, mutect2, varscan2
- MUC5B | c.2810T>C p.I937T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV71593417; called by muse, mutect2, varscan2
- MYH15 | c.2856del p.R953Gfs*10 | Frame Shift Del (DEL) | VAF 136/421 reads (32%) | catalogued as rs765618753; called by mutect2, pindel, varscan2
- MYO15A | c.4397G>T p.G1466V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV52761927; called by muse, mutect2, varscan2
- MYO5A | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 43/195 reads (22%) | catalogued as rs1343400784, COSV62562940; called by muse, mutect2, varscan2
- MYOC | c.1249T>C p.W417R | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50676833; called by muse, mutect2, varscan2
- MYOM2 | c.3271C>T p.Q1091* | Nonsense Mutation (SNP) | VAF 63/444 reads (14%) | catalogued as COSV50745346; called by muse, varscan2
- NAALAD2 | c.2009G>A p.G670D | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472327803, COSV58964196; called by muse, mutect2, varscan2
- NCOR1 | c.4543C>T p.H1515Y | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1227019947, COSV51965602; called by muse, mutect2, varscan2
- NCOR2 | c.1591_1593del p.K531del | In Frame Del (DEL) | VAF 21/128 reads (16%) | catalogued as rs1418191685; called by mutect2, pindel, varscan2
- NECTIN1 | c.317A>T p.D106V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50604556; called by muse, mutect2, varscan2
- NEFH | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.965); catalogued as rs754121553, COSV60219346; called by muse, mutect2, varscan2
- NFATC2 | c.1079G>T p.R360M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV65359214; called by muse, mutect2, varscan2
- NIBAN3 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56312139; called by muse, mutect2, varscan2
- NIN | c.185T>A p.V62E | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55400306; called by muse, mutect2, varscan2
- NOMO3 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 169/419 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs752615349, COSV53770308; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 134/331 reads (40%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NPRL2 | c.684-4_684-3dup | Splice Region (INS) | VAF 28/145 reads (19%) | catalogued as rs749481228; called by mutect2, varscan2
- NPTN | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750676855, COSV54739002; called by muse, mutect2, varscan2
- NUP133 | c.1075T>A p.W359R | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV54573970; called by muse, mutect2, varscan2
- NUP155 | c.2807C>T p.A936V (on ENST00000231498 / NM_153485.3; = p.A877V on NM_004298.4) | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as COSV51532927; called by muse, mutect2, varscan2
- NUP210 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99595511; called by muse, mutect2, varscan2
- OBSCN | c.9697C>T p.R3233C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs367605500; called by muse, mutect2, varscan2
- OLFM2 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321457; called by muse, mutect2
- OR6C74 | c.626T>A p.L209Q | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59606931; called by muse, mutect2, varscan2
- OTOF | c.2631G>T p.E877D (on ENST00000272371 / NM_194248.3; = p.E130D on NM_004802.4) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV55512430; called by muse, mutect2, varscan2
- OTUD7A | c.1374G>A p.A458= (on ENST00000307050 / NM_001382637.1; = p.A451= on NM_130901.3) | Splice Region (SNP) | VAF 22/50 reads (44%) | catalogued as rs760089268, COSV61041635; called by muse, mutect2, varscan2
- OVOL2 | c.809A>G p.E270G | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV53861469; called by muse, mutect2, varscan2
- PAGE2 | c.200A>G p.D67G | Missense Mutation (SNP) | VAF 223/548 reads (41%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); catalogued as COSV66596137; called by muse, mutect2, varscan2
- PARD3B | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 161/369 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV62522663; called by muse, mutect2, varscan2
- PARK7 | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.44); catalogued as rs758016497, CP035457, COSV58580329; called by muse, mutect2, varscan2
- PASK | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.15); catalogued as COSV52153143, COSV99298585; called by muse, mutect2, varscan2
- PCDH15 | c.4064G>A p.R1355Q | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs371850442; called by muse, mutect2, varscan2
- PCDH17 | c.119G>T p.R40M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs774440820, COSV100931408; called by muse, mutect2
- PCDH17 | c.2141C>T p.T714I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV64977070; called by muse, mutect2, varscan2
- PCDHB5 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.508); catalogued as rs1331528803, COSV50656851; called by muse, mutect2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 73/190 reads (38%) | catalogued as COSV61618667; called by mutect2, varscan2
- PDGFRA | c.2201T>C p.M734T | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs774628734, COSV57271498; called by muse, mutect2, varscan2
- PEAR1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs372909968; called by muse, mutect2
- PI16 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs1369919578, COSV65321183; called by muse, mutect2, varscan2
- PKD1L1 | c.1071dup p.H358Sfs*30 | Frame Shift Ins (INS) | VAF 70/176 reads (40%) | catalogued as rs544774439; called by mutect2, varscan2
- PLA2R1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs34979630; called by muse, mutect2, varscan2
- PLEKHH3 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs757023086, COSV53190619; called by muse, mutect2, varscan2
- PLS3 | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 43/228 reads (19%) | catalogued as rs868995558, COSV56780937; called by muse, mutect2, varscan2
- PLXNA1 | c.2474G>A p.R825H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs369081095; called by muse, mutect2, varscan2
- PNKP | c.888C>A p.N296K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.204); catalogued as COSV55589420; called by muse, mutect2, varscan2
- POLRMT | c.3248G>A p.R1083H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1393596779, COSV52113683; called by muse, mutect2, varscan2
- POMP | c.380T>C p.M127T | Missense Mutation (SNP) | VAF 152/388 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV66481770; called by muse, mutect2, varscan2
- PPP1R12A | c.826A>G p.I276V | Missense Mutation (SNP) | VAF 169/416 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs771702951, COSV54111860; called by muse, mutect2, varscan2
- PRDM11 | c.380del p.P127Rfs*40 (on ENST00000530656 / NM_001359633.1; = p.P93Rfs*40 on NM_001256695.1) | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | catalogued as COSV55440445; called by mutect2, pindel, varscan2
- PRDM4 | c.2089A>G p.T697A | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV57306949; called by muse, mutect2, varscan2
- PRKCQ | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs764066187, COSV54115857; called by muse, mutect2, varscan2
- PRPF8 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59266170; called by muse, mutect2, varscan2
- PRSS12 | c.2572G>C p.V858L | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV56608507; called by muse, mutect2, varscan2
- PRUNE2 | c.7298C>T p.A2433V | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV65044970; called by muse, mutect2, varscan2
- PTCH2 | c.2642del p.P881Hfs*112 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | catalogued as rs1337855606; called by mutect2, pindel, varscan2
- PTHLH | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 171/425 reads (40%) | catalogued as COSV52366593; called by muse, mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 62/350 reads (18%) | catalogued as rs778292578; called by mutect2, varscan2
- PTPRD | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.209); catalogued as rs768826930, COSV61936097; called by mutect2, varscan2
- PXDNL | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs889963192, COSV100681049, COSV100686804; called by mutect2, varscan2
- RAB38 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as rs371255484; called by muse, mutect2, varscan2
- RAD52 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV57273748; called by mutect2, varscan2
- RAE1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs780225824, COSV64798145; called by muse, mutect2, varscan2
- RALGAPA2 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs755240772, COSV52493252; called by muse, mutect2, varscan2
- RALGAPA2 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 31/175 reads (18%) | catalogued as COSV52505401; called by muse, mutect2, varscan2
- RAPGEF4 | c.1523T>A p.I508N | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs755235277, COSV51381498; called by muse, mutect2, varscan2
- RIMS2 | c.2945G>A p.R982Q (on ENST00000666250 / NM_001348490.2; = p.R790Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs747545747, COSV51668880; called by muse, mutect2, varscan2
- RIMS3 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); catalogued as rs1486758049, COSV65505091; called by muse, mutect2, varscan2
- RNASE1 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV61754147; called by muse, mutect2, varscan2
- RNF111 | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.255); catalogued as COSV62084234; called by muse, mutect2, varscan2
- RNF40 | c.2429T>C p.L810S | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61215980; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel
- ROBO1 | c.2265del p.F755Lfs*28 | Frame Shift Del (DEL) | VAF 64/304 reads (21%) | catalogued as rs1192824348; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 58/142 reads (41%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs747317928, COSV53705278; called by muse, mutect2, varscan2
- RYR1 | c.2976C>A p.H992Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62105042; called by muse, mutect2, varscan2
- SALL4 | c.985C>A p.R329S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV53854735; called by muse, mutect2, varscan2
- SCAF4 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 25/176 reads (14%) | catalogued as COSV54590504; called by muse, mutect2, varscan2
- SERINC3 | c.1133C>G p.T378S | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0.014); catalogued as COSV54857852; called by muse, mutect2, varscan2
- SETD1A | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52690853, COSV52694064; called by muse, mutect2, varscan2
- SFMBT1 | c.2489T>G p.L830R | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99965797; called by muse, mutect2
- SIGIRR | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV58989032; called by muse, mutect2, varscan2
- SIPA1L1 | c.4555C>T p.R1519C | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs765858688, COSV62172307; called by muse, mutect2, varscan2
- SLC22A8 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs780060603, COSV60323958, COSV60325475; called by muse, mutect2, varscan2
- SLC26A2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.587); catalogued as rs369318758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC28A2 | c.833T>A p.L278Q | Missense Mutation (SNP) | VAF 141/362 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61664814; called by muse, mutect2, varscan2
- SLC44A1 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66026741; called by muse, mutect2, varscan2
- SLC47A2 | c.1751C>G p.A584G | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99449558; called by muse, varscan2
- SLC5A5 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV55834445; called by muse, mutect2, varscan2
- SLC7A13 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.297); catalogued as rs990311495, COSV52536166; called by muse, mutect2, varscan2
- SLFN12 | c.555dup p.D186* | Frame Shift Ins (INS) | VAF 42/117 reads (36%) | catalogued as rs747319777; called by mutect2, varscan2
- SMC5 | c.2431A>G p.R811G | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.229); catalogued as COSV63194707; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 36/309 reads (12%) | catalogued as rs768873484; called by mutect2, varscan2
- SORBS2 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV53009643; called by muse, mutect2, varscan2
- SORCS1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); catalogued as COSV53864378; called by muse, mutect2, varscan2
- SPNS1 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1436950573, COSV57955945; called by muse, mutect2, varscan2
- STAB2 | c.4459G>A p.D1487N | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.698); catalogued as COSV66343806; called by muse, mutect2, varscan2
- STAG2 | c.2992G>A p.A998T | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as COSV54367449; called by muse, mutect2, varscan2
- STS | c.1358A>G p.Q453R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1220237043, COSV54270579; called by muse, mutect2, varscan2
- SYNCRIP | c.1379A>G p.Y460C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.397); catalogued as COSV62288867; called by muse, mutect2, varscan2
- TBC1D10B | c.2197_2199del p.K733del | In Frame Del (DEL) | VAF 92/508 reads (18%) | catalogued as rs1567410761; called by mutect2, pindel, varscan2
- TBC1D19 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 19/510 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53516268, COSV99335903; called by muse, mutect2
- TGFB2 | c.1217T>C p.M406T | Missense Mutation (SNP) | VAF 103/263 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65110338; called by muse, mutect2, varscan2
- TGM5 | c.1321A>G p.T441A (on ENST00000220420 / NM_201631.4; = p.T359A on NM_004245.4) | Missense Mutation (SNP) | VAF 135/337 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55011365; called by muse, mutect2, varscan2
- THBS3 | c.198del p.K67Sfs*24 | Frame Shift Del (DEL) | VAF 41/119 reads (34%) | catalogued as rs35627916; called by mutect2, pindel, varscan2
- TIAM1 | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs773421646, COSV54536911; called by muse, mutect2, varscan2
- TMC3 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV63924006; called by muse, mutect2, varscan2
- TMCO3 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs1423898660, COSV64808585; called by muse, mutect2, varscan2
- TMEM132D | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1271494578, COSV70616268; called by muse, varscan2
- TMEM255B | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs747109815, COSV64704552; called by muse, mutect2, varscan2
- TMEM61 | c.541A>G p.S181G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100987722; called by muse, mutect2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 106/186 reads (57%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 38/91 reads (42%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TNS1 | c.2600A>C p.N867T | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV50738662; called by muse, mutect2, varscan2
- TOGARAM2 | c.446del p.G149Efs*21 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs1164433985; called by mutect2, pindel, varscan2
- TOP2B | c.3757G>A p.A1253T (on ENST00000264331 / NM_001330700.2; = p.A1248T on NM_001068.3) | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs1297460082, COSV51975303; called by muse, mutect2, varscan2
- TP53INP2 | c.89A>T p.D30V | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV66351366; called by muse, mutect2, varscan2
- TPCN1 | c.2253+1G>A p.X751_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as rs577287446, COSV59237971; called by muse, mutect2, varscan2
- TPSG1 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as COSV52356867; called by muse, mutect2, varscan2
- TRAK1 | c.508A>G p.M170V (on ENST00000327628 / NM_001349247.2; = p.M112V on NM_014965.5) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs750343645, COSV58262134; called by muse, mutect2, varscan2
- TRAM1 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.18); catalogued as COSV51599158; called by muse, mutect2, varscan2
- TRIO | c.8533C>T p.Q2845* | Nonsense Mutation (SNP) | VAF 47/112 reads (42%) | catalogued as COSV59991838; called by muse, mutect2, varscan2
- TRPC6 | c.1128del p.K376Nfs*3 | Frame Shift Del (DEL) | VAF 38/148 reads (26%) | catalogued as COSV60250864; called by mutect2, pindel, varscan2
- TRPM1 | c.4411C>T p.Q1471* | Nonsense Mutation (SNP) | VAF 27/229 reads (12%) | catalogued as COSV56639140; called by muse, mutect2, varscan2
- TSGA10 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV61824704; called by muse, mutect2, varscan2
- TTBK1 | c.1316del p.P439Qfs*16 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as COSV104389590; called by mutect2, pindel, varscan2
- TTC24 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs755069741, COSV63998204; called by muse, varscan2
- TTN | c.93518G>T p.R31173M (on ENST00000591111; = p.R23749M on NM_003319.4) | Missense Mutation (SNP) | VAF 44/169 reads (26%) | PolyPhen probably damaging (0.998); catalogued as COSV60231044; called by muse, mutect2, varscan2
- TUBB4B | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs996340578, COSV61118322; called by muse, mutect2, varscan2
- TYROBP | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.139); catalogued as rs1167496461, COSV52888276; called by muse, mutect2, varscan2
- U2AF2 | c.371C>A p.T124N | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.381); catalogued as COSV58275569; called by muse, mutect2, varscan2
- UBR4 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64395531; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 100/398 reads (25%) | catalogued as rs763652408; called by mutect2, varscan2
- UBTD1 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as rs1332044288, COSV53969111; called by muse, mutect2, varscan2
- UBXN11 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs536230329, COSV100122798, COSV59027540; called by muse, mutect2, varscan2
- UGT3A1 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs554821154, COSV57095384; called by muse, mutect2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 50/214 reads (23%) | catalogued as rs767420916; called by mutect2, varscan2
- USH2A | c.1828C>T p.H610Y | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56408766; called by muse, mutect2, varscan2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 48/200 reads (24%) | catalogued as rs749830910; called by mutect2, varscan2
- USP7 | c.3205A>G p.N1069D | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.042); catalogued as COSV61216413; called by muse, mutect2, varscan2
- UTRN | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 119/306 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs762571654, COSV62342770; called by muse, mutect2, varscan2
- VIRMA | c.3019C>T p.R1007C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as rs755374889, COSV52584000; called by muse, mutect2, varscan2
- VWA3B | c.3688G>A p.G1230S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs759997020, COSV71371258; called by muse, mutect2, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | catalogued as rs773064295, COSV51967888; called by pindel, varscan2
- WDR18 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV52122911; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WWC3 | c.2214G>T p.E738D | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as COSV66505724; called by muse, mutect2, varscan2
- ZBTB9 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV101221725; called by muse, mutect2
- ZC3H11A | c.2225T>C p.V742A | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV59748716; called by muse, mutect2, varscan2
- ZDHHC11 | c.234del p.I79Sfs*10 | Frame Shift Del (DEL) | VAF 22/97 reads (23%) | catalogued as rs761252759, COSV52080829; called by mutect2, varscan2
- ZMYND10 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs150467144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF22 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs867738898, COSV53584435; called by muse, mutect2, varscan2
- ZNF250 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 110/219 reads (50%) | catalogued as COSV52970178; called by muse, mutect2, varscan2
- ZNF292 | c.7684C>T p.R2562C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.153); catalogued as rs749404949, COSV60536795; called by muse, mutect2, varscan2
- ZNF326 | c.1211C>G p.T404R | Missense Mutation (SNP) | VAF 152/365 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61035974; called by muse, mutect2, varscan2
- ZNF564 | c.577G>T p.G193* | Nonsense Mutation (SNP) | VAF 46/311 reads (15%) | catalogued as COSV59436011; called by muse, mutect2, varscan2
- ZNF665 | c.1685G>T p.R562M (on ENST00000600412; = p.R627M on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 141/335 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV101127908; called by muse, mutect2
- ZNF678 | c.143G>A p.C48Y (on ENST00000343776 / NM_001367910.1; = p.C103Y on NM_178549.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59385826; called by muse, mutect2, varscan2
- ZNF800 | c.1322del p.K441Rfs*61 | Frame Shift Del (DEL) | VAF 23/224 reads (10%) | catalogued as rs1346638445; called by mutect2, pindel, varscan2
- ZNF836 | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 54/413 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV59084992; called by muse, mutect2, varscan2
- ZPBP | c.757T>C p.C253R | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50430269; called by muse, mutect2, varscan2
- ZZEF1 | c.5435-2A>G p.X1812_splice | Splice Site (SNP) | VAF 17/104 reads (16%) | catalogued as COSV67559216; called by muse, mutect2, varscan2
- ABCA13 | c.6509dup p.S2171Lfs*7 | Frame Shift Ins (INS) | VAF 43/108 reads (40%) | called by mutect2, pindel, varscan2
- ABLIM2 | c.1051dup p.D351Gfs*4 | Frame Shift Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- ALCAM | c.833del p.P278Qfs*15 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- ARHGEF5 | c.4540del p.Q1514Rfs*24 | Frame Shift Del (DEL) | VAF 19/174 reads (11%) | called by mutect2, pindel
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- ASCL4 | c.109del p.L37Sfs*53 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- ATP8A1 | c.243dup p.L82Sfs*11 | Frame Shift Ins (INS) | VAF 95/281 reads (34%) | called by mutect2, pindel, varscan2
- C16orf71 | c.1118_1119del p.E373Vfs*7 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | called by pindel, varscan2
- C9 | c.423del p.C142Afs*6 | Frame Shift Del (DEL) | VAF 63/170 reads (37%) | called by mutect2, pindel, varscan2
- CDKAL1 | c.1002_1003del p.E336Ifs*5 | Frame Shift Del (DEL) | VAF 87/244 reads (36%) | called by mutect2, pindel, varscan2
- CFAP36 | c.369dup p.A124Sfs*14 | Frame Shift Ins (INS) | VAF 32/160 reads (20%) | called by mutect2, pindel, varscan2
- CRB1 | c.4199del p.P1400Lfs*6 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | called by mutect2, pindel, varscan2
- CSNK1A1L | c.249del p.D84Tfs*5 | Frame Shift Del (DEL) | VAF 28/268 reads (10%) | called by mutect2, pindel, varscan2
- DDR1 | c.2326dup p.E776Gfs*50 (on ENST00000324771; = p.E739Gfs*50 on NM_001954.4) | Frame Shift Ins (INS) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- DOCK1 | c.5546del p.P1849Lfs*75 | Frame Shift Del (DEL) | VAF 58/143 reads (41%) | called by mutect2, pindel, varscan2
- ECM2 | c.65del p.N22Mfs*17 | Frame Shift Del (DEL) | VAF 36/235 reads (15%) | called by mutect2, pindel, varscan2
- EPG5 | c.6830_6832dup p.M2277dup | In Frame Ins (INS) | VAF 40/176 reads (23%) | called by mutect2, varscan2
- EPHA4 | c.191del p.N64Ifs*12 | Frame Shift Del (DEL) | VAF 25/156 reads (16%) | called by mutect2, pindel, varscan2
- EPHB1 | c.399del p.Y134Tfs*4 | Frame Shift Del (DEL) | VAF 66/165 reads (40%) | called by mutect2, pindel, varscan2
- EXOC4 | c.1287dup p.A430Cfs*37 | Frame Shift Ins (INS) | VAF 66/202 reads (33%) | called by mutect2, pindel, varscan2
- FAM133A | c.623del p.K208Rfs*15 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- FAM135A | c.2996dup p.N999Kfs*2 (on ENST00000370479 / NM_001351599.1; = p.N786Kfs*2 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 26/79 reads (33%) | called by mutect2, varscan2
- GON4L | c.400del p.M134* | Frame Shift Del (DEL) | VAF 48/196 reads (24%) | called by mutect2, varscan2
- GPHB5 | c.225del p.Y76Ifs*17 | Frame Shift Del (DEL) | VAF 53/269 reads (20%) | called by mutect2, pindel, varscan2
- HECTD2 | c.1144dup p.I382Nfs*22 | Frame Shift Ins (INS) | VAF 89/250 reads (36%) | called by mutect2, varscan2
- HID1 | c.583dup p.Q195Pfs*3 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- HSPH1 | c.1375del p.I459* | Frame Shift Del (DEL) | VAF 17/154 reads (11%) | called by mutect2, pindel, varscan2
- IGSF10 | c.4758del p.G1587Afs*6 | Frame Shift Del (DEL) | VAF 146/417 reads (35%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 34/188 reads (18%) | called by mutect2, varscan2
- KIF3A | c.699del p.G234Afs*16 | Frame Shift Del (DEL) | VAF 76/236 reads (32%) | called by mutect2, pindel, varscan2
- LRFN4 | c.679dup p.L227Pfs*6 | Frame Shift Ins (INS) | VAF 7/14 reads (50%) | called by mutect2, varscan2
- MED24 | c.2109del p.K704Sfs*8 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- MED24 | c.1255_1258del p.N419Sfs*42 | Frame Shift Del (DEL) | VAF 91/386 reads (24%) | called by mutect2, pindel, varscan2
- MNT | c.1159del p.H387Tfs*69 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- OR7C1 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 72/188 reads (38%) | called by mutect2, varscan2
- P2RY12 | c.698del p.K233Rfs*2 | Frame Shift Del (DEL) | VAF 56/166 reads (34%) | called by mutect2, pindel, varscan2
- PDZD4 | c.1031del p.G344Afs*63 | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | called by mutect2, pindel, varscan2
- PRPF4B | c.3019dup p.I1007Nfs*13 | Frame Shift Ins (INS) | VAF 58/170 reads (34%) | called by mutect2, pindel, varscan2
- RAI1 | c.2396del p.P799Lfs*20 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | called by mutect2, varscan2
- RALGAPA2 | c.944del p.K315Sfs*3 | Frame Shift Del (DEL) | VAF 57/274 reads (21%) | called by mutect2, pindel, varscan2
- RBBP6 | c.4594dup p.S1532Kfs*2 | Frame Shift Ins (INS) | VAF 19/72 reads (26%) | called by mutect2, varscan2
- RBP3 | c.2202C>A p.F734L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.232); called by muse, mutect2
- RHOA | c.561del p.K187Nfs*19 | Frame Shift Del (DEL) | VAF 260/735 reads (35%) | called by mutect2, pindel, varscan2
- SENP3 | c.1345del p.D449Tfs*9 | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | called by mutect2, pindel, varscan2
- SLC26A5 | c.169del p.I57* | Frame Shift Del (DEL) | VAF 47/148 reads (32%) | called by mutect2, pindel, varscan2
- SOGA3 | c.2835dup p.V946Cfs*28 | Frame Shift Ins (INS) | VAF 36/275 reads (13%) | called by mutect2, pindel, varscan2
- SPDYE3 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.11); called by mutect2, varscan2
- SPTBN2 | c.2771del p.P924Qfs*35 | Frame Shift Del (DEL) | VAF 55/304 reads (18%) | called by mutect2, pindel, varscan2
- STN1 | c.766_768del p.K256del | In Frame Del (DEL) | VAF 124/313 reads (40%) | called by pindel, varscan2
- STPG1 | c.531_532del p.G179Ifs*6 (on ENST00000337248 / NM_001199013.2; = p.G132Ifs*6 on NM_178122.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 56/167 reads (34%) | called by mutect2, pindel, varscan2
- TNFAIP3 | c.1097_1098del p.E366Gfs*22 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by pindel, varscan2
- TOX2 | c.286del p.D96Tfs*38 (on ENST00000358131 / NM_001098798.2; = p.D45Tfs*38 on NM_032883.3) | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | called by mutect2, pindel, varscan2
- TRIM9 | c.1983del p.F661Lfs*10 | Frame Shift Del (DEL) | VAF 62/260 reads (24%) | called by mutect2, pindel, varscan2
- TXLNB | c.1372del p.I458Sfs*43 | Frame Shift Del (DEL) | VAF 26/284 reads (9%) | called by mutect2, pindel
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- ZNF507 | c.2152_2153del p.E718Tfs*14 | Frame Shift Del (DEL) | VAF 38/244 reads (16%) | called by pindel, varscan2
- AC104452.1 | c.1086T>C p.P362= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV56470431; called by muse, mutect2, varscan2
- ACAP2 | c.1314C>T p.S438= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs755440839, COSV100461411; called by muse, mutect2
- ADAM8 | c.276C>T p.G92= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV101291598; called by muse, mutect2, varscan2
- AFF2 | c.2781C>T p.R927= | Silent (SNP) | VAF 9/212 reads (4%) | catalogued as COSV99661716; called by muse, mutect2
- AKT3 | c.1188A>G p.A396= | Silent (SNP) | VAF 39/282 reads (14%) | catalogued as COSV55626218; called by muse, mutect2, varscan2
- ANKRD11 | c.945C>T p.D315= | Silent (SNP) | VAF 46/348 reads (13%) | catalogued as rs780080339, COSV56367547; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD17 | c.2940G>A p.L980= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as COSV58215501, COSV58225209; called by muse, mutect2, varscan2
- AP1B1 | c.2139A>G p.S713= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV58020256; called by muse, mutect2, varscan2
- APCDD1 | c.603C>T p.A201= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs145453912, COSV62372937; called by muse, mutect2, varscan2
- ARHGEF17 | c.6126C>T p.G2042= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs554421422, COSV99734822; called by muse, mutect2
- ASPM | c.975T>C p.S325= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV54135053; called by muse, mutect2, varscan2
- ATG4C | c.21T>C p.D7= | Silent (SNP) | VAF 71/218 reads (33%) | catalogued as COSV58607399; called by muse, mutect2, varscan2
- BMPER | c.1842C>T p.I614= | Silent (SNP) | VAF 23/206 reads (11%) | catalogued as COSV51827043; called by muse, mutect2, varscan2
- BRCA1 | c.1041G>A p.L347= | Silent (SNP) | VAF 65/319 reads (20%) | catalogued as rs1555592609, COSV58790983; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRICD5 | c.702G>A p.Q234= (on ENST00000562360; = p.Q202= on NM_182563.3) | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV57030598; called by muse, mutect2, varscan2
- C17orf67 | c.195T>G p.A65= | Silent (SNP) | VAF 35/152 reads (23%) | catalogued as COSV67375602; called by muse, mutect2, varscan2
- C2CD2L | c.828C>A p.P276= | Silent (SNP) | VAF 28/183 reads (15%) | catalogued as COSV60884502; called by muse, mutect2, varscan2
- CCDC88B | c.1476G>A p.P492= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs758184933, COSV57267392; called by muse, mutect2, varscan2
- CCT2 | c.1368T>C p.Y456= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV54741052; called by muse, mutect2, varscan2
- CEP290 | c.543T>C p.I181= | Silent (SNP) | VAF 89/463 reads (19%) | catalogued as COSV58354278; called by muse, mutect2, varscan2
- CHD1 | c.3687T>G p.P1229= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as COSV99399058; called by muse, mutect2
- CLDN8 | c.358C>T p.L120= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as rs370704016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX42 | c.438T>C p.G146= | Silent (SNP) | VAF 57/503 reads (11%) | catalogued as COSV63790853; called by muse, mutect2, varscan2
- DHX8 | c.141G>A p.K47= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV52255363; called by muse, mutect2, varscan2
- DNER | c.1326C>T p.N442= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs201881122, COSV59161793; called by muse, mutect2
- DSE | c.405G>A p.A135= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs1231116205, COSV59066471; called by muse, mutect2, varscan2
- ELOVL6 | c.519G>A p.V173= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1378870340, COSV56431174; called by muse, mutect2, varscan2
- ENTPD7 | c.972C>T p.Y324= | Silent (SNP) | VAF 90/184 reads (49%) | catalogued as rs144074709; called by muse, mutect2, varscan2
- ERCC6L | c.3336A>G p.E1112= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as COSV57821650; called by muse, mutect2, varscan2
- EVI5L | c.474C>T p.I158= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs1457659109, COSV54487635; called by muse, mutect2, varscan2
- FGD2 | c.1542C>T p.Y514= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs756823723, COSV51462678; called by muse, mutect2, varscan2
- GAB4 | c.834G>A p.Q278= | Silent (SNP) | VAF 23/152 reads (15%) | catalogued as COSV68754661; called by muse, mutect2, varscan2
- GREM1 | c.333C>A p.R111= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV55715779; called by muse, mutect2, varscan2
- HGS | c.222C>T p.N74= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs749899003, COSV61269485; called by muse, mutect2, varscan2
- HGSNAT | c.1815C>T p.H605= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs1249488528, COSV52818201; called by muse, mutect2, varscan2
- HSPA2 | c.1698C>T p.S566= | Silent (SNP) | VAF 47/175 reads (27%) | catalogued as COSV55970793; called by muse, mutect2, varscan2
- ICMT | c.696C>T p.C232= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs778429985, COSV59473707; called by muse, varscan2
- ILDR1 | c.189G>A p.K63= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV56552188; called by muse, mutect2, varscan2
- ILKAP | c.375C>T p.H125= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as rs769962569, COSV54519359; called by muse, mutect2, varscan2
- ISL1 | c.747G>A p.Q249= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV57934941; called by muse, mutect2, varscan2
- IST1 | c.504A>G p.E168= (on ENST00000535424 / NM_001270976.1; = p.E155= on NM_014761.4) | Silent (SNP) | VAF 38/195 reads (19%) | catalogued as rs1191100123, COSV61710673; called by muse, mutect2, varscan2
- ITPRIPL1 | c.300C>T p.G100= (on ENST00000439118 / NM_001008949.3; = p.G108= on NM_178495.6) | Silent (SNP) | VAF 32/211 reads (15%) | catalogued as COSV63154188; called by muse, mutect2, varscan2
- KCND1 | c.591C>T p.A197= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1557058556, COSV54415326; called by muse, mutect2, varscan2
- KCNG3 | c.711C>T p.I237= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as rs750630963, COSV60150172; called by muse, mutect2, varscan2
- KCNH8 | c.1026G>A p.L342= | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as COSV60471668; called by muse, mutect2, varscan2
- KRT13 | c.564C>T p.D188= | Silent (SNP) | VAF 32/214 reads (15%) | catalogued as rs368494222; called by muse, varscan2
- KRTAP5-10 | c.441C>T p.P147= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as rs765810364, COSV100924121; called by muse, mutect2, varscan2
- LAMA2 | c.4806G>A p.L1602= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV70352563; called by muse, mutect2, varscan2
- LNPEP | c.2709G>A p.V903= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV99183468; called by muse, mutect2, varscan2
- LOXL2 | c.2211C>T p.D737= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as rs373978855; called by muse, mutect2, varscan2
- LRRC4C | c.1320C>T p.T440= | Silent (SNP) | VAF 62/151 reads (41%) | catalogued as COSV53433457, COSV99540171; called by muse, mutect2, varscan2
- LYN | c.1104G>A p.L368= | Silent (SNP) | VAF 39/247 reads (16%) | catalogued as COSV70206183; called by muse, mutect2, varscan2
- MAGEE2 | c.315G>A p.T105= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs769020872, COSV64897697; called by muse, mutect2, varscan2
- MAGI2 | c.141G>A p.V47= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV62684536; called by muse, mutect2, varscan2
- MUC16 | c.10533T>C p.P3511= | Silent (SNP) | VAF 114/278 reads (41%) | catalogued as COSV67506658; called by muse, mutect2
- MUC5B | c.14376G>A p.V4792= | Silent (SNP) | VAF 81/332 reads (24%) | catalogued as rs758236048, COSV71594348; called by muse, mutect2, varscan2
- MYH7 | c.5451G>A p.A1817= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as rs138682220; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO10 | c.4491C>T p.D1497= | Silent (SNP) | VAF 12/270 reads (4%) | catalogued as COSV57027022, COSV99944601; called by muse, mutect2
- NCL | c.909G>A p.P303= | Silent (SNP) | VAF 53/192 reads (28%) | catalogued as rs149517418; called by muse, mutect2, varscan2
- NECTIN4 | c.1173C>A p.T391= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs1029114337, COSV63513532; called by muse, mutect2, varscan2
- NEURL4 | c.3483C>T p.I1161= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs375197335; called by muse, mutect2, varscan2
- NEUROD1 | c.141C>T p.N47= | Silent (SNP) | VAF 140/320 reads (44%) | catalogued as rs1046216784, COSV54549546; called by muse, mutect2, varscan2
- NOP53 | c.966C>T p.A322= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs562399482, COSV55882674; called by muse, mutect2, varscan2
- NOSTRIN | c.396G>A p.Q132= (on ENST00000317647 / NM_001039724.4; = p.Q54= on NM_052946.3) | Silent (SNP) | VAF 29/241 reads (12%) | catalogued as COSV58323232; called by muse, mutect2, varscan2
- NRDE2 | c.181C>T p.L61= | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as rs1367084898, COSV62964209; called by muse, mutect2, varscan2
- NSD3 | c.2037C>T p.D679= | Silent (SNP) | VAF 10/222 reads (5%) | catalogued as rs1216484018, COSV100388445; called by muse, mutect2
- OBP2B | c.498C>T p.C166= | Silent (SNP) | VAF 48/276 reads (17%) | catalogued as rs576469540, COSV64402753; called by muse, mutect2, varscan2
- OR5D18 | c.810C>T p.H270= | Silent (SNP) | VAF 69/253 reads (27%) | catalogued as COSV100450892, COSV61738130; called by muse, mutect2, varscan2
- OR9A4 | c.766T>C p.L256= | Silent (SNP) | VAF 30/213 reads (14%) | catalogued as COSV71885830; called by muse, mutect2, varscan2
- OVCH1 | c.354T>C p.N118= | Silent (SNP) | VAF 133/336 reads (40%) | catalogued as COSV58966286; called by muse, mutect2, varscan2
- PABPC1L | c.1632G>A p.A544= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs550882592, COSV53841896; called by muse, mutect2, varscan2
- PAPOLG | c.1914T>C p.T638= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as COSV53184447; called by muse, mutect2, varscan2
- PCDHA3 | c.2190C>T p.G730= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV63542786; called by muse, mutect2, varscan2
- PKP2 | c.901C>T p.L301= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs1565599048, CD155480, COSV50740203; ClinVar: likely benign; called by muse, mutect2, varscan2
- POLR1A | c.1645C>T p.L549= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as COSV55697095; called by muse, mutect2, varscan2
- PPP1R12A | c.1272A>G p.K424= | Silent (SNP) | VAF 143/376 reads (38%) | catalogued as COSV54111849; called by muse, mutect2, varscan2
- PRKD2 | c.1569G>A p.A523= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs142760319; called by muse, mutect2, varscan2
- RASSF6 | c.369C>T p.V123= (on ENST00000342081 / NM_201431.2; = p.V91= on NM_177532.5) | Silent (SNP) | VAF 77/197 reads (39%) | catalogued as COSV56720065; called by muse, mutect2, varscan2
- RCC2 | c.1092C>T p.H364= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs367926411; called by muse, mutect2, varscan2
- RDH13 | c.249C>T p.R83= (on ENST00000415061 / NM_001145971.2; = p.R12= on NM_138412.4) | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs756106983, COSV52562107; called by muse, mutect2, varscan2
- RFT1 | c.129C>A p.I43= | Silent (SNP) | VAF 104/233 reads (45%) | catalogued as COSV56248287, COSV56249820; called by muse, mutect2, varscan2
- RRP12 | c.2814T>C p.S938= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV59670109; called by muse, mutect2, varscan2
- SCN4A | c.48C>T p.C16= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs765207978, COSV71128067; called by muse, mutect2
- SEMA5A | c.375C>T p.G125= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs893534225, COSV66795144; called by muse, mutect2, varscan2
- SH3BP4 | c.366C>T p.S122= | Silent (SNP) | VAF 55/190 reads (29%) | catalogued as rs372707115; called by muse, mutect2, varscan2
- SHISA2 | c.450G>A p.Q150= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100096437, COSV60111542; called by muse, mutect2, varscan2
- SHROOM4 | c.3411G>A p.E1137= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs781966917, COSV56785285; called by muse, mutect2, varscan2
- SIMC1 | c.1491C>A p.P497= (on ENST00000443967 / NM_001308196.1; = p.P82= on NM_198567.5) | Silent (SNP) | VAF 34/185 reads (18%) | catalogued as COSV57905544; called by muse, mutect2, varscan2
- SLC12A4 | c.1713C>T p.I571= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as rs370106833; called by muse, mutect2, varscan2
- SLC17A3 | c.489C>T p.G163= | Silent (SNP) | VAF 78/294 reads (27%) | catalogued as rs769368252, COSV57761070; called by muse, mutect2, varscan2
- SLC18A1 | c.1182C>T p.G394= | Silent (SNP) | VAF 75/171 reads (44%) | catalogued as rs772765643, COSV52350252; called by muse, mutect2, varscan2
- SLC25A12 | c.1317T>C p.S439= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as COSV55535473; called by muse, mutect2, varscan2
- SLC34A1 | c.492C>T p.S164= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs1335153351, COSV60998034; called by muse, mutect2, varscan2
- SLC9A7 | c.2073G>A p.T691= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as rs868709707, COSV60382377; called by muse, mutect2, varscan2
- SORBS2 | c.1761G>A p.E587= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV53009659, COSV99512945; called by muse, mutect2, varscan2
- STAB2 | c.6396C>T p.N2132= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs141685973; called by muse, mutect2, varscan2
- SYNGR2 | c.573C>A p.A191= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV56746320; called by muse, mutect2, varscan2
- TEX43 | c.123G>A p.K41= | Silent (SNP) | VAF 101/283 reads (36%) | catalogued as COSV64036249; called by muse, mutect2, varscan2
- TG | c.4029C>A p.S1343= | Silent (SNP) | VAF 165/418 reads (39%) | catalogued as COSV55088202; called by muse, mutect2, varscan2
- TNC | c.2829C>T p.S943= | Silent (SNP) | VAF 38/239 reads (16%) | called by muse, mutect2, varscan2
- TRRAP | c.6873C>T p.S2291= (on ENST00000359863 / NM_001244580.1; = p.S2273= on NM_003496.3) | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as rs778900327, COSV100722629, COSV62850941; called by muse, mutect2, varscan2
- USP5 | c.1908C>T p.N636= | Silent (SNP) | VAF 39/205 reads (19%) | catalogued as rs373638224; called by muse, mutect2, varscan2
- USP9X | c.285A>G p.E95= | Silent (SNP) | VAF 79/529 reads (15%) | catalogued as COSV61072944; called by muse, mutect2, varscan2
- XRCC3 | c.889C>T p.L297= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV57979402; called by muse, mutect2, varscan2
- YBEY | c.345G>A p.T115= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV52449873; called by muse, mutect2, varscan2
- ZFC3H1 | c.1071G>A p.L357= | Silent (SNP) | VAF 32/339 reads (9%) | catalogued as rs1215415391, COSV101110293; called by muse, mutect2
- ZFHX3 | c.10584G>A p.S3528= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs377246983, COSV51711967; called by muse, mutect2, varscan2
- ZNF502 | c.1425C>T p.S475= | Silent (SNP) | VAF 13/177 reads (7%) | catalogued as COSV99939547; called by muse, mutect2
- ZNF721 | c.2439T>C p.T813= (on ENST00000338977; = p.T825= on NM_133474.4) | Silent (SNP) | VAF 57/222 reads (26%) | catalogued as COSV59091032, COSV59095398; called by muse, mutect2, varscan2
- ZNF85 | c.897A>G p.S299= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV60216305; called by muse, mutect2, varscan2
- DENND10P1 | n.474G>T | RNA (SNP) | VAF 213/593 reads (36%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446773 C>T | 3'Flank (SNP) | VAF 56/147 reads (38%) | called by muse, mutect2, varscan2
- FCRL5 | c.*2T>A | 3'UTR (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100708496; called by muse, mutect2, varscan2
- ITCH | c.1548-3706del | Intron (DEL) | VAF 104/486 reads (21%) | called by mutect2, pindel, varscan2
- LAMA3 | c.4998+1530T>G | Intron (SNP) | VAF 23/108 reads (21%) | catalogued as COSV52539771; called by muse, mutect2, varscan2
- MIR323A | n.36G>A | RNA (SNP) | VAF 128/318 reads (40%) | catalogued as rs1040944663; called by muse, mutect2, varscan2
- SDF4 | c.892-27G>A | Intron (SNP) | VAF 32/76 reads (42%) | catalogued as rs745351256, COSV55420636; called by muse, varscan2
- SSPOP | n.3328G>A | RNA (SNP) | VAF 7/31 reads (23%) | catalogued as rs372027582, COSV50488419; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.*74del | 3'UTR (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
